Somatic mutation profile of tumor specimen TARGET-10-PASJJR-09A (aliquot TARGET-10-PASJJR-09A-01D) from TARGET case TARGET-10-PASJJR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,216 days).
Specimen TARGET-10-PASJJR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6016304-f0a9-48b4-8a38-fdef442606b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASJJR-10A (Blood Derived Normal), aliquot TARGET-10-PASJJR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/769c36d6-fe1b-461b-8eef-9cb26ffe09f5

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Ins 3, Nonsense Mutation 2, Silent 2, Splice Region 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKMY1 | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV56037012; called by muse, varscan2
- CASP8 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51854284; called by muse, mutect2, varscan2
- CHRM3 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV55080302; called by muse, mutect2
- CLEC12A | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV100429421, COSV58561819; called by muse, mutect2, varscan2
- FAM135B | c.3700C>T p.R1234W | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757525959, COSV52703914, COSV52737505; called by muse, mutect2, varscan2
- GALNT18 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as rs372293544; called by muse, mutect2, varscan2
- GASK1B | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as rs769147496, COSV56708948; called by muse, mutect2, varscan2
- HMCN1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753817944, COSV54915726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFNLR1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs200381326, COSV59526975; called by muse, mutect2, varscan2
- JAK3 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV71686796; called by muse, mutect2
- KMT2C | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV51402639, COSV51501644; called by muse, mutect2, varscan2
- MOK | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51966125; called by muse, mutect2, varscan2
- SCN4A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs374529559, COSV71126821; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZNF19 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55508163; called by muse, mutect2, varscan2
- AHNAK2 | c.10052T>C p.L3351P | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- APAF1 | c.1151C>A p.T384K (on ENST00000551964 / NM_181861.2; = p.T373K on NM_001160.3) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DENND6B | c.560-2A>G p.X187_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2
- ETV6 | c.613dup p.L205Pfs*12 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- EXOC3L4 | c.1474C>A p.L492I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- HIVEP1 | c.1908C>A p.D636E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- KDM6A | c.3337_3338insGGTGTCG p.V1113Gfs*40 | Frame Shift Ins (INS) | VAF 24/38 reads (63%) | called by mutect2, pindel, varscan2
- MRNIP | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); called by mutect2, varscan2
- PRPF38B | c.343delinsCCCC p.G115delinsPR | Splice Region (INS) | VAF 12/38 reads (32%) | called by pindel, varscan2*
- UTY | c.3266_3267insACCGCCCG p.T1090Pfs*18 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- PLEC | c.10845G>T p.V3615= (on ENST00000322810 / NM_201380.4; = p.V3505= on NM_000445.5) | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- RBBP6 | c.1215T>A p.A405= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-5265G>A | Intron (SNP) | VAF 64/156 reads (41%) | called by muse, mutect2, varscan2
